Somatic mutation profile of tumor specimen TCGA-BR-6566-01A (aliquot TCGA-BR-6566-01A-11D-1800-08) from TCGA case TCGA-BR-6566, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 64.1 years (23,404 days).
Specimen TCGA-BR-6566-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75c19664-d293-4267-b726-716cbc8ba9be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6566-10A (Blood Derived Normal), aliquot TCGA-BR-6566-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/754b7caa-5734-477c-9467-b972efef49be

The open-access MAF lists 1,008 somatic variants for this specimen: 765 protein-altering or splice-affecting, 223 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 519, Silent 223, Frame Shift Del 169, Frame Shift Ins 26, Nonsense Mutation 17, Splice Site 17, Splice Region 9, Intron 7, In Frame Del 5, 5'UTR 4, RNA 3, 5'Flank 3.

Variants (750 of 1,008; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTA2 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.09); catalogued as rs112901682, CM112673, CM156145, COSV56518131; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.8494C>T p.R2832C | Missense Mutation (SNP) | VAF 38/181 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779872, CM980159, COSV53732886, COSV53761977; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 39/182 reads (21%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- B2M | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1057519877, COSV62562849, COSV62563168, COSV62564729; ClinVar: likely pathogenic; called by muse, varscan2
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- COL1A2 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057524847, COSV51967450; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen possibly damaging (0.599); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.3131G>A p.C1044Y | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730880100, CM040035, COSV57332471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- IVD | c.899C>T p.A300V (on ENST00000651168; = p.A297V on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs796051983, CM149148, COSV51102357; ClinVar: likely pathogenic; called by muse, mutect2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 25/134 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 13/26 reads (50%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NAGLU | c.648dup p.S217Lfs*56 | Frame Shift Ins (INS) | VAF 25/186 reads (13%) | catalogued as rs760370189; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs573607437; ClinVar: pathogenic; called by pindel, varscan2
- SLC26A2 | c.438del p.F146Lfs*26 | Frame Shift Del (DEL) | VAF 22/132 reads (17%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by mutect2, varscan2
- WDFY3 | c.7909C>T p.R2637W | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553924800, COSV55715813; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAMP | c.880-1G>T p.X294_splice | Splice Site (SNP) | VAF 7/127 reads (6%) | catalogued as COSV99815946; called by muse, mutect2
- ABCA4 | c.5616G>T p.W1872C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64679011; called by muse, mutect2, varscan2
- ABCC8 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1203692637, COSV56858759; called by muse, mutect2, varscan2
- ABCD1 | c.640A>G p.N214D | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as CM993103, COSV54388271; called by muse, mutect2, varscan2
- ABHD6 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs1448310634, COSV55910692; called by muse, mutect2, varscan2
- ABO | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1192853615, COSV71743709; called by muse, mutect2, varscan2
- ACAA2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs145076043; called by muse, mutect2, varscan2
- ACACB | c.2916T>C p.A972= | Splice Region (SNP) | VAF 14/294 reads (5%) | catalogued as rs1413183436, COSV58148514; called by muse, mutect2
- ACACB | c.4769A>C p.N1590T | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58148521; called by muse, mutect2
- ACD | c.1105G>A p.G369S (on ENST00000620338; = p.G280S on NM_022914.3) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1260047390, COSV54670840; called by muse, mutect2
- ACTL7B | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV65928284; called by muse, mutect2, varscan2
- ACTR8 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV51639011; called by muse, mutect2, varscan2
- ACVR1B | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57774926; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 54/116 reads (47%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM29 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63668431, COSV63668954; called by muse, mutect2, varscan2
- ADAMTS9 | c.2008A>G p.N670D | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs767334673, COSV55792258; called by muse, mutect2, varscan2
- ADCY8 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV53902161; called by muse, mutect2, varscan2
- ADGRG2 | c.911C>T p.P304L (on ENST00000379869 / NM_001079858.3; = p.P301L on NM_005756.4) | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.063); catalogued as COSV61341758, COSV61341945; called by muse, mutect2, varscan2
- ADGRG3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs149201757; called by muse, mutect2, varscan2
- AFF1 | c.3232A>G p.N1078D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV57125262; called by muse, mutect2, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as COSV58317085; called by mutect2, pindel
- AGO4 | c.1759G>T p.G587* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV64619004; called by muse, mutect2, varscan2
- AGRN | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as rs750287607, COSV65072719; called by muse, mutect2, varscan2
- AHCY | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1445336414, COSV54154702; called by muse, mutect2
- AKAP9 | c.2483A>G p.E828G | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1296930462, COSV62359282; called by muse, mutect2
- AL136295.1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 29/443 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55782382; called by muse, mutect2
- ALPI | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs903671931, COSV55013859; called by muse, mutect2, varscan2
- AMBRA1 | c.2590T>C p.W864R (on ENST00000458649 / NM_001367468.1; = p.W774R on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV54063693; called by muse, mutect2, varscan2
- AMER1 | c.2099C>A p.P700H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57670263; called by muse, mutect2, varscan2
- AMIGO3 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57540426; called by muse, mutect2, varscan2
- AMPD3 | c.96G>T p.E32D (on ENST00000396553 / NM_001025389.2; = p.E41D on NM_000480.3) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as COSV67332903; called by muse, mutect2, varscan2
- ANK2 | c.7316C>T p.A2439V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV52192735; called by muse, mutect2, varscan2
- APP | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1360205184, COSV61005876; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASB10 | c.415C>T p.R139* (on ENST00000420175 / NM_001142459.2; = p.R124* on NM_080871.4) | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs148812712; called by muse, varscan2
- ATAD3B | c.719G>T p.R240M (on ENST00000308647; = p.R346M on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58023518; called by muse, mutect2, varscan2
- ATL3 | c.1472G>T p.R491M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60298567; called by muse, mutect2
- ATP13A1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV52291967; called by muse, mutect2, varscan2
- ATP2B1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53814233; called by muse, mutect2
- ATP4A | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52872456; called by muse, mutect2, varscan2
- ATXN2 | c.2965A>G p.M989V (on ENST00000550104; = p.M829V on NM_002973.4) | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.824); catalogued as rs1168598221, COSV66486332; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- BBS2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762922907, COSV55325032; called by muse, mutect2
- BCL3 | c.1224del p.R409Gfs*73 | Frame Shift Del (DEL) | VAF 86/565 reads (15%) | catalogued as COSV51234121; called by mutect2, pindel, varscan2
- BEX2 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV65500596; called by muse, mutect2, varscan2
- BID | c.520G>A p.A174T (on ENST00000317361 / NM_197966.2; = p.A128T on NM_001196.4) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); catalogued as COSV58008485; called by muse, mutect2, varscan2
- BOC | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs772475137, COSV56347972; called by muse, mutect2, varscan2
- BRAT1 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.026); catalogued as COSV61397568; called by muse, mutect2, varscan2
- BRWD1 | c.3919del p.S1307Afs*19 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs1296036169; called by mutect2, pindel, varscan2
- BTN3A1 | c.1337A>C p.E446A | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV50025473; called by muse, mutect2, varscan2
- C12orf45 | c.551del p.K184Rfs*13 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs777032057; called by mutect2, varscan2
- C18orf25 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs757216745, COSV56366973; called by muse, mutect2, varscan2
- C1QTNF1 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.99); catalogued as COSV59264831; called by muse, mutect2, varscan2
- C1QTNF7 | c.237A>G p.A79= | Splice Region (SNP) | VAF 10/53 reads (19%) | catalogued as COSV54857027; called by muse, mutect2, varscan2
- C1QTNF9B | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1332037690, COSV65944696; called by muse, mutect2, varscan2
- C1orf158 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55348227; called by muse, mutect2
- C20orf27 | c.419T>C p.V140A (on ENST00000379772 / NM_001258429.2; = p.V165A on NM_001039140.3) | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV53925625; called by muse, mutect2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C4BPB | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54692915; called by muse, mutect2, varscan2
- C6orf118 | c.35A>C p.K12T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); catalogued as COSV57820179; called by muse, mutect2, varscan2
- CACNG3 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs1488719446, COSV50086419; called by muse, mutect2, varscan2
- CAMSAP1 | c.3907G>A p.V1303M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs375382345, COSV56729206; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARMIL1 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV61524893; called by muse, mutect2
- CATSPER4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs768987248, COSV58794089; called by muse, mutect2, varscan2
- CBLN2 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54053328, COSV99504602; called by muse, mutect2, varscan2
- CCDC158 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs769628925, COSV66357366; called by muse, mutect2, varscan2
- CCDC189 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs138413324, COSV60314081; called by muse, mutect2, varscan2
- CCDC40 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53905165; called by muse, mutect2, varscan2
- CCKBR | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV58098769; called by muse, mutect2, varscan2
- CCR2 | c.107A>T p.D36V | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV52750384; called by muse, mutect2, varscan2
- CD180 | c.1712C>T p.T571I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs867512896, COSV56520216; called by muse, mutect2, varscan2
- CD1D | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV63808731; called by muse, mutect2, varscan2
- CD200R1 | c.371T>C p.I124T (on ENST00000471858 / NM_170780.3; = p.I147T on NM_138806.4) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as COSV99866992; called by muse, mutect2
- CD300A | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV60411267; called by muse, mutect2, varscan2
- CD5L | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV63821414; called by muse, mutect2, varscan2
- CDADC1 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs376714185; called by muse, mutect2, varscan2
- CDCA4 | c.602del p.G201Vfs*46 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | catalogued as COSV60315065; called by mutect2, pindel, varscan2
- CDH1 | c.688-1G>A p.X230_splice | Splice Site (SNP) | VAF 28/260 reads (11%) | catalogued as CS142882, COSV55728760; called by muse, mutect2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | catalogued as rs752398646; called by mutect2, pindel
- CDH7 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59896322; called by muse, mutect2, varscan2
- CDHR2 | c.3616C>A p.P1206T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV56146266; called by muse, mutect2, varscan2
- CEMIP2 | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV100987199, COSV65489958; called by muse, mutect2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CEP83 | c.577_579del p.E193del | In Frame Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs369249734; called by pindel, varscan2
- CEP85L | c.116T>G p.L39W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV63829308; called by muse, mutect2, varscan2
- CERCAM | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV65712027; called by mutect2, varscan2
- CFHR3 | c.880del p.T294Qfs*30 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as COSV100807378; called by mutect2, pindel, varscan2
- CIAO3 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761989802, COSV52402625; called by muse, mutect2, varscan2
- CIDEA | c.490A>C p.T164P | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.755); catalogued as COSV57601061; called by muse, mutect2, varscan2
- CLMN | c.11A>G p.H4R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54189305; called by muse, mutect2, varscan2
- CLSTN1 | c.1832G>A p.R611Q (on ENST00000377298 / NM_001009566.3; = p.R601Q on NM_014944.4) | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1394547462, COSV63651659; called by muse, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTRL | c.1346-2A>G p.X449_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV53054433; called by muse, mutect2, varscan2
- COG7 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as rs747918109, COSV56153702; called by muse, mutect2, varscan2
- COL7A1 | c.6004C>T p.R2002C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773400450, CM994041, COSV60404164; called by muse, mutect2, varscan2
- COL7A1 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.878); catalogued as rs375923118; called by muse, mutect2, varscan2
- COMMD5 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.209); catalogued as COSV100521886, COSV59312060; called by muse, mutect2, varscan2
- COPS8 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs752671265, COSV100585458, COSV62976893; called by muse, mutect2
- COQ10A | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs187670547, COSV57526110; called by muse, mutect2, varscan2
- CPVL | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as rs376043843, COSV55307453; called by muse, mutect2, varscan2
- CRACDL | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168021661, COSV67408148; called by muse, mutect2, varscan2
- CREB3L2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1420597509, COSV57800930; called by muse, mutect2, varscan2
- CREBBP | c.4492C>T p.R1498* | Nonsense Mutation (SNP) | VAF 13/267 reads (5%) | catalogued as CM021084, COSV52113607; called by muse, mutect2
- CREBBP | c.3415A>G p.K1139E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52143344; called by muse, varscan2
- CRYBA1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs757580467, COSV56601631; called by muse, mutect2, varscan2
- CRYBB3 | c.161A>C p.E54A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV53195641; called by muse, mutect2, varscan2
- CSMD1 | c.8423G>A p.R2808H (on ENST00000520002; = p.R2807H on NM_033225.6) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs774812490, COSV59359077; called by muse, mutect2, varscan2
- CSPG4 | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as rs374349137; called by muse, mutect2, varscan2
- CTNNB1 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.217); catalogued as COSV62700025, COSV62704421; called by muse, mutect2, varscan2
- CUTC | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs749464623, COSV65081544; called by muse, mutect2, varscan2
- CWC22 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs780645038, COSV55427432; called by muse, mutect2
- CYLC2 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66338398, COSV66339743; called by muse, mutect2, varscan2
- CYP27A1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs748904875, COSV51470217; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs751187768; called by mutect2, varscan2
- DAPK2 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99977212; called by muse, mutect2, varscan2
- DCAF8L1 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV71595569; called by muse, mutect2, varscan2
- DDR1 | c.2303C>T p.A768V (on ENST00000324771; = p.A731V on NM_001954.4) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61326802; called by muse, mutect2
- DDX19B | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1334802142, COSV55365068; called by muse, mutect2, varscan2
- DENND4B | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs767143683, COSV63412349; called by muse, mutect2, varscan2
- DERL3 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV51954958; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DGKE | c.1400A>G p.Y467C | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52351678; called by muse, mutect2, varscan2
- DIP2C | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55181975; called by muse, mutect2, varscan2
- DISP1 | c.2486A>G p.H829R | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52665948; called by muse, mutect2, varscan2
- DLL1 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV64536853; called by muse, mutect2, varscan2
- DMRT3 | c.1282C>A p.R428S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51909084, COSV99505697; called by muse, mutect2, varscan2
- DNAH10 | c.3172C>T p.R1058* (on ENST00000409039; = p.R997* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 44/117 reads (38%) | catalogued as rs1449530904, COSV68991805; called by muse, mutect2, varscan2
- DNAH5 | c.13631G>A p.G4544D | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV54256722; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 24/140 reads (17%) | catalogued as rs774662919; called by mutect2, varscan2
- DNHD1 | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV54444251; called by muse, mutect2, varscan2
- DOCK11 | c.4716A>C p.E1572D | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV52248870; called by muse, mutect2, varscan2
- DOCK8 | c.2524C>T p.H842Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV66624407; called by muse, mutect2, varscan2
- DPP6 | c.2333C>T p.A778V (on ENST00000377770 / NM_001364500.2; = p.A716V on NM_001936.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs201710106, COSV59609066; called by muse, mutect2, varscan2
- DRD5 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.188); catalogued as COSV58580844; called by muse, mutect2, varscan2
- DSTYK | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs780479792, COSV65688734; called by muse, mutect2, varscan2
- DTNB | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748641272, COSV56473777; called by muse, mutect2, varscan2
- DYNLT3 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV66079173; called by muse, mutect2, varscan2
- E2F8 | c.1066+2T>C p.X356_splice | Splice Site (SNP) | VAF 8/198 reads (4%) | catalogued as COSV51466512; called by muse, mutect2
- ECHDC1 | c.237A>G p.S79= (on ENST00000531967 / NM_001139510.1; = p.S73= on NM_018479.3) | Splice Region (SNP) | VAF 7/52 reads (13%) | catalogued as rs533378725, COSV58934573; called by muse, mutect2, varscan2
- ECPAS | c.3959C>T p.A1320V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs1200768239, COSV52209081; called by muse, mutect2, varscan2
- EDNRB | c.311C>T p.A104V (on ENST00000377211 / NM_001201397.1; = p.A14V on NM_000115.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as rs548023225, COSV57519093; called by muse, mutect2, varscan2
- EFCAB7 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs759233815, COSV64313883, COSV64315530; called by muse, varscan2
- EFNB3 | c.836del p.G279Vfs*15 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs1241382696; called by mutect2, pindel
- EIF4ENIF1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV57518479; called by muse, mutect2, varscan2
- EIF4G1 | c.2927G>A p.R976H (on ENST00000346169 / NM_198241.3; = p.R781H on NM_004953.5) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59994718; called by muse, mutect2, varscan2
- ELMO3 | c.1240G>A p.V414M (on ENST00000652269; = p.V361M on NM_024712.5) | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs375789407; called by muse, mutect2, varscan2
- ENOX2 | c.840G>T p.E280D (on ENST00000338144 / NM_001382520.1; = p.E251D on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.82); catalogued as COSV57658926; called by muse, mutect2, varscan2
- ENPP5 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57909048, COSV57910239; called by muse, mutect2, varscan2
- EP300 | c.3591-1G>T p.X1197_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | catalogued as COSV54331549; called by muse, mutect2, varscan2
- EPB41L3 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.187); catalogued as COSV59470361; called by muse, mutect2, varscan2
- EPG5 | c.6950C>T p.A2317V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56354653; called by muse, mutect2
- EPHB4 | c.1969C>G p.Q657E | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62270819; called by muse, mutect2, varscan2
- EPHB4 | c.1298-1G>C p.X433_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV62270824; called by muse, mutect2
- EPM2AIP1 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV51625294; called by muse, mutect2
- EPPK1 | c.746A>C p.E249A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV73262463; called by muse, mutect2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 12/62 reads (19%) | catalogued as rs768793415; called by mutect2, varscan2
- ERC1 | c.2574G>A p.M858I (on ENST00000360905 / NM_178040.4; = p.M830I on NM_178039.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV61696767, COSV61696993; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs753821453; called by mutect2, varscan2
- EVC2 | c.1007T>G p.V336G | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV60404329; called by muse, mutect2, varscan2
- EWSR1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.318); catalogued as rs777722463, COSV53323835; called by muse, mutect2, varscan2
- EXOC3L1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1282582652, COSV52048650; called by muse, varscan2
- EXOC8 | c.1940T>C p.L647P | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50480209; called by muse, mutect2
- EXPH5 | c.5159C>T p.T1720I | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as rs755367080, COSV56209237; called by muse, mutect2, varscan2
- FAHD2B | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.331); catalogued as COSV99737979; called by muse, mutect2, varscan2
- FAM124B | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54740238; called by muse, mutect2
- FAM13C | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.3); catalogued as COSV53257052; called by muse, mutect2, varscan2
- FAM166A | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs749911273, COSV100458183, COSV61119213; called by muse, mutect2, varscan2
- FAM166A | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs142886368; called by mutect2, varscan2
- FAM209A | c.307del p.R103Efs*14 | Frame Shift Del (DEL) | VAF 47/154 reads (31%) | catalogued as COSV54769575; called by mutect2, pindel, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs746881923; called by mutect2, varscan2
- FAM50B | c.364T>G p.F122V | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66655342; called by muse, mutect2, varscan2
- FASTKD3 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52951645; called by muse, mutect2
- FASTKD3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52947355; called by muse, mutect2, varscan2
- FAT2 | c.3714T>A p.N1238K | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV55831172; called by muse, mutect2, varscan2
- FAT3 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53080643; called by muse, mutect2, varscan2
- FAT4 | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as COSV67902260; called by muse, mutect2, varscan2
- FAT4 | c.5285T>C p.L1762P | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58712296; called by muse, mutect2, varscan2
- FAT4 | c.5873C>A p.P1958H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392034328, COSV58712305; called by muse, mutect2, varscan2
- FBL | c.670C>A p.R224S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55684274; called by muse, mutect2, varscan2
- FBLN1 | c.1492T>C p.C498R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53054836; called by muse, mutect2, varscan2
- FBLN7 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767206123, COSV55617519; called by muse, mutect2, varscan2
- FBN3 | c.8006C>T p.S2669L | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs772366972, COSV54474861; called by muse, mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 8/89 reads (9%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBXL18 | c.1423T>C p.F475L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV66107932; called by muse, mutect2, varscan2
- FBXO45 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.955); catalogued as rs779907832, COSV61147024, COSV61147251; called by muse, mutect2, varscan2
- FERD3L | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51761976, COSV51764624; called by muse, mutect2, varscan2
- FERMT1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs777736000, COSV54098399; called by muse, mutect2, varscan2
- FGFR2 | c.1708G>C p.G570R | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60661896; called by muse, mutect2, varscan2
- FIGN | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV60772298, COSV60772349; called by muse, mutect2, varscan2
- FIP1L1 | c.228G>A p.P76= | Splice Region (SNP) | VAF 5/46 reads (11%) | catalogued as COSV60994684, COSV61000254; called by muse, mutect2, varscan2
- FLG | c.6439G>C p.G2147R | Missense Mutation (SNP) | VAF 150/577 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs746864718, COSV100912335, COSV64238766, COSV64251212; called by muse, mutect2, varscan2
- FLT4 | c.1097T>C p.F366S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV56124558; called by muse, mutect2, varscan2
- FOXD4L5 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.425); catalogued as rs1170995864, COSV101073089; called by muse, mutect2
- FOXN3 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.843); catalogued as COSV54318121; called by muse, mutect2, varscan2
- FREM1 | c.2174C>A p.A725D | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66531433; called by muse, mutect2
- FRY | c.3526G>T p.G1176C | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66581626; called by muse, mutect2, varscan2
- FSD1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55699302; called by muse, mutect2, varscan2
- FYCO1 | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56120474; called by muse, mutect2
- FZD7 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs752131418, COSV53811749; called by muse, mutect2, varscan2
- GAD2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs754627728, COSV52150827, COSV52170231; called by muse, mutect2, varscan2
- GBP5 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58594584; called by muse, mutect2, varscan2
- GBP5 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV58594590; called by muse, mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 32/188 reads (17%) | catalogued as rs754177800; called by mutect2, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 37/164 reads (23%) | catalogued as rs755348339; called by mutect2, pindel, varscan2
- GDE1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs537541856, COSV62059313; called by muse, mutect2, varscan2
- GDF10 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782499950; called by muse, mutect2, varscan2
- GJA8 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782805555, COSV53789424; called by muse, mutect2, varscan2
- GLIPR1L2 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.055); catalogued as rs1243788629, COSV57556626; called by muse, mutect2, varscan2
- GNPTAB | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68450029; called by muse, mutect2, varscan2
- GP1BA | c.1480del p.T494Pfs*59 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | catalogued as rs759573909; called by mutect2, pindel
- GPR142 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV59520634; called by muse, mutect2, varscan2
- GPR143 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); catalogued as COSV66633343; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 44/153 reads (29%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR37L1 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs374873137; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK5 | c.862T>C p.W288R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); catalogued as COSV53486968; called by muse, mutect2, varscan2
- GRIN2B | c.3625C>T p.R1209W | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1488088518, COSV74208290; called by muse, mutect2, varscan2
- GRIPAP1 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 46/134 reads (34%) | catalogued as COSV64552686, COSV64553581; called by muse, mutect2, varscan2
- GRM6 | c.727del p.V243Sfs*21 | Frame Shift Del (DEL) | VAF 18/173 reads (10%) | catalogued as rs281865186, CM1514172; ClinVar: not provided; called by mutect2, pindel, varscan2
- GSG1L | c.928C>G p.P310A (on ENST00000447459 / NM_001109763.2; = p.P155A on NM_144675.2) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.111); catalogued as COSV66583085; called by muse, mutect2, varscan2
- GTPBP3 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV50197047, COSV50202521; called by muse, mutect2
- GZMH | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1422733352, COSV53539576; called by muse, mutect2, varscan2
- HAUS6 | c.2636T>G p.L879R | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.483); catalogued as COSV65840951; called by muse, mutect2
- HEBP2 | c.593dup p.N198Kfs*2 | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | catalogued as rs769528102; called by mutect2, varscan2
- HEYL | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1270682957, COSV65722141; called by muse, mutect2
- HHIP | c.1196C>G p.T399R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.999); catalogued as COSV56844811; called by muse, mutect2, varscan2
- HJURP | c.1832A>G p.K611R | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV64979684; called by muse, mutect2, varscan2
- HK1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV53867283; called by muse, mutect2
- HNRNPK | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.781); catalogued as rs760176912, COSV61091320; called by muse, mutect2, varscan2
- HNRNPM | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV57694943; called by muse, mutect2, varscan2
- HOXA6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1000312377, COSV56073009; called by muse, mutect2
- HSD17B7 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV54420026; called by muse, mutect2, varscan2
- HSPA4L | c.2077A>G p.M693V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1444513341, COSV56545760; called by muse, mutect2
- HTR1F | c.886G>T p.G296* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV60391485; called by muse, mutect2
- HYDIN | c.244del p.E82Kfs*39 | Frame Shift Del (DEL) | VAF 32/198 reads (16%) | catalogued as COSV55481517; called by mutect2, pindel, varscan2
- IGDCC4 | c.2613del p.T872Qfs*11 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as COSV61539288; called by mutect2, pindel
- IL1RAPL1 | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56234364; called by muse, mutect2
- ILF2 | c.6-2A>G p.X2_splice | Splice Site (SNP) | VAF 22/98 reads (22%) | catalogued as COSV62628298; called by muse, mutect2, varscan2
- INCENP | c.1663C>T p.R555C (on ENST00000394818 / NM_001040694.2; = p.R551C on NM_020238.3) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs200313762; called by muse, mutect2, varscan2
- INPP5F | c.788del p.P263Lfs*7 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as rs750419826; called by mutect2, pindel, varscan2
- IQCH | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs765558699, COSV60056889; called by muse, mutect2, varscan2
- ITGB4 | c.3368del p.P1123Lfs*37 | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | catalogued as rs1441262033; called by mutect2, pindel, varscan2
- ITGB4 | c.5246C>G p.A1749G | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV52330911; called by muse, mutect2, varscan2
- ITIH2 | c.2639C>A p.P880H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64435532; called by muse, mutect2, varscan2
- IVNS1ABP | c.1865C>T p.T622M | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1486998891, COSV62250531; called by muse, mutect2, varscan2
- KAT8 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54896209; called by muse, mutect2
- KCNA4 | c.992A>C p.E331A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV60256436; called by muse, mutect2, varscan2
- KCNF1 | c.1034T>C p.M345T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV54465891; called by muse, mutect2, varscan2
- KCNH3 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57793360; called by muse, mutect2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 40/190 reads (21%) | catalogued as COSV99236896; called by pindel, varscan2
- KCTD7 | c.453+4C>T | Splice Region (SNP) | VAF 13/107 reads (12%) | catalogued as COSV51876783; called by muse, mutect2, varscan2
- KIAA1522 | c.172del p.H58Tfs*24 (on ENST00000373480 / NM_001198972.2; = p.H117Tfs*24 on NM_020888.3) | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as rs767600627; called by mutect2, pindel, varscan2
- KIF21B | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59751995; called by muse, mutect2, varscan2
- KIF4A | c.3101T>C p.F1034S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65546317; called by muse, mutect2, varscan2
- KIRREL2 | c.379del p.Q127Rfs*18 | Frame Shift Del (DEL) | VAF 16/145 reads (11%) | catalogued as rs758018108; called by mutect2, pindel, varscan2
- KLF11 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773276131, COSV59941806; called by muse, mutect2, varscan2
- KLF3 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54712914; called by muse, mutect2
- KLK9 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV51593604; called by muse, mutect2
- KMT2A | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.162); catalogued as COSV63293388; called by muse, mutect2, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KMT5C | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs778714300, COSV55320620; called by muse, mutect2, varscan2
- KPNA6 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65362403; called by muse, mutect2
- KRT33B | c.72del p.S25Afs*17 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs752320759; called by mutect2, pindel, varscan2
- KYAT3 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs941326432, COSV53103463; called by muse, mutect2, varscan2
- LARGE1 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs747003834, COSV61673681; called by muse, mutect2, varscan2
- LARGE2 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs368165815; called by muse, mutect2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARS1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as COSV50994251; called by muse, mutect2, varscan2
- LEXM | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV64024440; called by muse, mutect2, varscan2
- LGALS9 | c.1037del p.G346Afs*5 (on ENST00000395473 / NM_009587.3; = p.G314Afs*5 on NM_002308.4) | Frame Shift Del (DEL) | VAF 25/240 reads (10%) | catalogued as rs775745717; called by mutect2, pindel, varscan2
- LMAN1L | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs530685001, COSV59003835; called by muse, mutect2, varscan2
- LONRF2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66542703; called by muse, mutect2, varscan2
- LRIF1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568800560, COSV63898553; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP1B | c.4262T>C p.M1421T | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as COSV67281508; called by muse, mutect2, varscan2
- LRP2 | c.2796A>T p.R932S | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV55578053; called by muse, mutect2, varscan2
- LRP6 | c.4384C>T p.R1462* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV53795822; called by muse, mutect2
- LRRC4B | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65349462; called by muse, mutect2, varscan2
- LRRC8D | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470893412, COSV61578030; called by muse, mutect2
- LRRIQ1 | c.5006T>C p.V1669A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV67839877; called by muse, mutect2, varscan2
- LRRK2 | c.6056G>A p.G2019D | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54156900; called by muse, mutect2
- LSG1 | c.1006T>C p.W336R | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1560223055, COSV54573049; called by muse, mutect2, varscan2
- LSS | c.1527dup p.H510Afs*18 | Frame Shift Ins (INS) | VAF 12/79 reads (15%) | catalogued as rs1335748816; called by mutect2, pindel, varscan2
- MAEA | c.991G>A p.A331T (on ENST00000303400 / NM_001017405.3; = p.A290T on NM_005882.5) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53265231; called by muse, mutect2
- MAGEA10 | c.579A>T p.E193D | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV54886338, COSV99726881; called by muse, mutect2, varscan2
- MAGEC1 | c.2109C>A p.D703E | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV53582617; called by muse, mutect2, varscan2
- MAGED2 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.986); catalogued as rs1227741576, COSV54499640; called by muse, mutect2, varscan2
- MAGEH1 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as rs1358204954, COSV61679316; called by muse, mutect2, varscan2
- MAMDC4 | c.2402C>T p.A801V (on ENST00000445819; = p.A722V on NM_206920.3) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); catalogued as COSV56377599; called by muse, mutect2, varscan2
- MAN1A1 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV63781353; called by muse, mutect2
- MAP2K1 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61069932, COSV61073949; called by muse, mutect2, varscan2
- MAP3K3 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.703); catalogued as COSV62281458, COSV62282027; called by muse, mutect2
- MAP7D3 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1321043572, COSV60172933; called by muse, mutect2, varscan2
- MARCKSL1 | c.246dup p.K83Qfs*33 | Frame Shift Ins (INS) | VAF 32/126 reads (25%) | catalogued as rs749563695; called by mutect2, varscan2
- MARF1 | c.2720del p.K907Sfs*6 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs1303520043; called by mutect2, pindel, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as rs746267361; called by mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs1180255648; called by mutect2, pindel
- MDN1 | c.13532C>T p.A4511V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV65531651; called by muse, mutect2, varscan2
- MDN1 | c.5703G>T p.M1901I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV65531656; called by muse, mutect2, varscan2
- MED12 | c.3851G>A p.R1284H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs979229015, COSV61357209, COSV61358364; called by muse, mutect2, varscan2
- MEFV | c.1781A>G p.Q594R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV54828410; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MET | c.3633-2A>G p.X1211_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as rs879254337, COSV59270535; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL17 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs771684327, COSV59557264; called by muse, mutect2, varscan2
- MEX3B | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV61664561; called by muse, mutect2, varscan2
- MFSD14A | c.806dup p.L269Ffs*43 | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD6 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.212); catalogued as COSV55625991; called by muse, mutect2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MGAT3 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.313); catalogued as COSV57869044; called by muse, mutect2, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs538500709; called by mutect2, varscan2
- MKRN3 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58811297, COSV58812599; called by muse, mutect2, varscan2
- MKRN3 | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769287405, COSV58812608; called by muse, mutect2, varscan2
- MLF1 | c.285A>C p.Q95H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV63034586, COSV63035457; called by muse, mutect2, varscan2
- MLX | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140676383; called by muse, mutect2, varscan2
- MPIG6B | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.442); catalogued as COSV65390457; called by muse, mutect2, varscan2
- MPP4 | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59635052; called by muse, mutect2, varscan2
- MTMR14 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV56008057; called by muse, mutect2, varscan2
- MTMR6 | c.1487G>T p.R496M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as COSV67810022; called by muse, mutect2, varscan2
- MUC16 | c.32528dup p.H10844Pfs*2 | Frame Shift Ins (INS) | VAF 28/146 reads (19%) | catalogued as rs745530053; called by mutect2, varscan2
- MYB | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776200677, COSV57199181; called by muse, mutect2, varscan2
- MYCBPAP | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1323801301, COSV60413097; called by muse, mutect2, varscan2
- MYH1 | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs980224192, COSV56856595; called by muse, mutect2, varscan2
- MYH8 | c.3046G>T p.E1016* | Nonsense Mutation (SNP) | VAF 51/234 reads (22%) | catalogued as COSV67963592, COSV67973815; called by muse, mutect2, varscan2
- MYOM2 | c.3692G>A p.C1231Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV50790116; called by muse, mutect2, varscan2
- NAALAD2 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV58966959; called by muse, mutect2, varscan2
- NADK | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1270606632, COSV58272857; called by muse, mutect2
- NAGLU | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.027); catalogued as rs146456266, COSV56794092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV1 | c.3632del p.K1211Rfs*17 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs770039235; called by mutect2, varscan2
- NCAN | c.2501C>T p.T834M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201846254, COSV53060322; called by muse, varscan2
- NCAN | c.2621C>T p.T874M | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs148196919; called by muse, varscan2
- NCDN | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.446); catalogued as rs752708609, COSV61934916; called by muse, mutect2, varscan2
- NCKAP1L | c.3328T>C p.Y1110H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53213234; called by muse, mutect2, varscan2
- NCKAP5 | c.4027G>T p.G1343W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV58479203; called by muse, mutect2, varscan2
- NCKAP5 | c.266del p.K89Sfs*6 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as COSV100495128; called by mutect2, pindel, varscan2
- NCOA4 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs782564433; called by muse, mutect2, varscan2
- NCOR2 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs771023965, COSV62299377; called by muse, mutect2, varscan2
- NDOR1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV59178929; called by muse, mutect2, varscan2
- NDUFS1 | c.1944A>C p.E648D | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV51914330; called by muse, mutect2, varscan2
- NEBL | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV65806337; called by muse, mutect2, varscan2
- NEBL | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV65806343; called by muse, mutect2, varscan2
- NEDD9 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760782051, COSV65219135; called by muse, mutect2, varscan2
- NEGR1 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs1327583553, COSV60877751; called by muse, mutect2, varscan2
- NETO1 | c.541G>T p.G181* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV55007823, COSV55016279; called by muse, mutect2, varscan2
- NEURL4 | c.4198A>G p.N1400D | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV59753684; called by muse, mutect2
- NFATC1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.083); catalogued as rs769008406, COSV53710611; called by muse, mutect2, varscan2
- NKG7 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs532047087, COSV52467330; called by muse, mutect2, varscan2
- NLRP1 | c.2972T>C p.V991A | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52580523; called by muse, mutect2, varscan2
- NOC3L | c.508+2T>C p.X170_splice | Splice Site (SNP) | VAF 14/109 reads (13%) | catalogued as COSV64930774; called by muse, mutect2, varscan2
- NOL6 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs981010966, COSV53046486; called by muse, mutect2, varscan2
- NOM1 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1481767968, COSV51983253; called by muse, mutect2, varscan2
- NOTCH4 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV66684444; called by muse, mutect2, varscan2
- NPAP1 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV61512201; called by muse, mutect2
- NPAP1 | c.1557G>C p.M519I | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.908); catalogued as COSV61512204; called by muse, mutect2, varscan2
- NPAP1 | c.1900A>T p.S634C | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV61508397, COSV61512207, COSV99051844; called by muse, mutect2, varscan2
- NPAS3 | c.469T>C p.S157P (on ENST00000356141 / NM_001164749.2; = p.S125P on NM_022123.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58116788; called by muse, mutect2
- NPS | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV67691033; called by muse, mutect2, varscan2
- NR1I2 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as rs780684359, COSV61979909; called by muse, mutect2, varscan2
- NR3C2 | c.2642-1G>T p.X881_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV61001110; called by muse, mutect2
- NR4A2 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59895074; called by muse, mutect2, varscan2
- NRDE2 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1253625221, COSV62964998; called by muse, mutect2, varscan2
- NRXN3 | c.2223del p.R742Vfs*8 (on ENST00000335750 / NM_001330195.2; = p.R369Vfs*8 on NM_004796.6) | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as COSV59808471; called by mutect2, pindel, varscan2
- NRXN3 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.05); catalogued as COSV99817435; called by muse, mutect2, varscan2
- NSD1 | c.5005C>T p.H1669Y | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61786135; called by muse, mutect2
- NUP85 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV55459363; called by muse, mutect2, varscan2
- OAS1 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV52539198; called by muse, mutect2
- OBSCN | c.9568G>A p.A3190T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.16); catalogued as COSV52741553, COSV52838856; called by muse, mutect2, varscan2
- OBSCN | c.19552G>A p.A6518T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201469382, COSV63548025; called by muse, mutect2
- OPA3 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55608591; called by muse, mutect2, varscan2
- OR11H4 | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1165942240, COSV59561043; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2F2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 47/417 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs529776575, COSV68833491; called by muse, mutect2, varscan2
- OR4S1 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60680420; called by muse, mutect2
- OR51I2 | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.371); catalogued as COSV100413453, COSV58300522; called by muse, mutect2, varscan2
- OR52B6 | c.325T>A p.Y109N | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV61448437; called by muse, mutect2, varscan2
- OR52E4 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as rs141226100; called by muse, mutect2, varscan2
- OR6B2 | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as COSV53156991; called by muse, mutect2, varscan2
- OR6C3 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV65572215; called by muse, mutect2
- OR7E24 | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV71702379; called by muse, mutect2, varscan2
- OR8I2 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56170930; called by muse, mutect2, varscan2
- OR8U1 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100163804, COSV56414852; called by muse, mutect2, varscan2
- OSBP2 | c.1887dup p.S630Lfs*79 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs772802379; called by mutect2, varscan2
- PALB2 | c.886del p.M296* | Frame Shift Del (DEL) | VAF 29/130 reads (22%) | catalogued as CD147527; called by mutect2, pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | catalogued as CM011452; called by pindel, varscan2
- PCARE | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as CM1410563, COSV59058697; called by muse, mutect2, varscan2
- PCDH8 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58811009; called by muse, mutect2, varscan2
- PCDHA11 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs782304708, COSV56552258; called by muse, mutect2, varscan2
- PCDHGA10 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as COSV54048469; called by muse, mutect2, varscan2
- PCDHGB3 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as rs1435194391, COSV53910636; called by muse, mutect2
- PCDHGB6 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV53991608; called by muse, varscan2
- PCDHGC3 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52748030; called by muse, mutect2, varscan2
- PCGF2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs554363495; called by muse, mutect2, varscan2
- PCK1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs747837917, COSV60126763, COSV60131546; called by muse, mutect2, varscan2
- PDIA5 | c.965T>A p.L322H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100299271, COSV60248321; called by muse, mutect2, varscan2
- PGAP1 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61330443; called by muse, mutect2
- PGRMC1 | c.242T>C p.F81S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV54293772; called by muse, mutect2, varscan2
- PHF3 | c.2910dup p.R971Sfs*6 | Frame Shift Ins (INS) | VAF 15/51 reads (29%) | catalogued as rs755026826; called by mutect2, varscan2
- PHLDA2 | c.349_357del p.T117_P119del | In Frame Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs752309318; called by mutect2, varscan2
- PI4KA | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV99745291; called by muse, mutect2, varscan2
- PIP5K1C | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58956541; called by muse, mutect2, varscan2
- PKD1 | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs750594767, COSV51927178; called by muse, mutect2
- PKM | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs2959910, CM097299, COSV100064656; called by muse, mutect2, varscan2
- PLCB3 | c.1778T>G p.L593R | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54192795; called by muse, mutect2, varscan2
- PLCE1 | c.3304G>A p.D1102N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.544); catalogued as rs763011760, COSV53335466; called by muse, mutect2, varscan2
- PLEC | c.10225C>T p.R3409C (on ENST00000322810 / NM_201380.4; = p.R3299C on NM_000445.5) | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs375101631, COSV59691362; called by muse, mutect2
- PLEKHM1 | c.2935G>A p.A979T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV69599539; called by muse, mutect2, varscan2
- PLXNB1 | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.951); catalogued as rs200470824, COSV56494769; called by muse, mutect2, varscan2
- PNMA5 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs782477423, COSV100721729, COSV62626408; called by muse, mutect2, varscan2
- PNPLA8 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448594898, COSV57554524; called by muse, mutect2, varscan2
- POGZ | c.3285G>T p.K1095N | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as COSV51853578; called by muse, mutect2, varscan2
- POLR1A | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs377398566; called by muse, mutect2
- POLR2M | c.466T>C p.S156P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55210974, COSV55212059; called by muse, mutect2, varscan2
- POTED | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV55051742; called by muse, mutect2, varscan2
- PPL | c.3040C>T p.R1014W | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs767821204, COSV52166270; called by muse, mutect2, varscan2
- PPP1R10 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 21/395 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as rs901654884, COSV64740656; called by muse, mutect2
- PPP1R21 | c.1227T>C p.S409= | Splice Region (SNP) | VAF 4/68 reads (6%) | catalogued as COSV54290295; called by muse, mutect2
- PPP2R1A | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV59049045; called by muse, mutect2, varscan2
- PPP5C | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs767506672, COSV50145490; called by muse, mutect2, varscan2
- PRAF2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.49); catalogued as rs782276544, COSV59877122; called by muse, mutect2, varscan2
- PROSER2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs771367449, COSV53208197; called by muse, mutect2
- PRRC2B | c.5039G>A p.R1680Q | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.956); catalogued as rs764922838, COSV57644517; called by muse, mutect2, varscan2
- PRSS36 | c.986del p.P329Rfs*12 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as COSV51635755; called by mutect2, pindel, varscan2
- PSMA7 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); catalogued as rs766775552, COSV53380424; called by mutect2, varscan2
- PSMC2 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV53009333; called by muse, mutect2, varscan2
- PTCH2 | c.3505del p.L1169Cfs*85 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | catalogued as rs763413121; called by mutect2, pindel, varscan2
- PTGES3L-AARSD1 | c.825del p.S276Lfs*2 (on ENST00000421990 / NM_001136042.2; = p.S258Lfs*2 on NM_025267.3) | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as COSV64183419, COSV64183622; called by mutect2, pindel, varscan2
- PTOV1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776677018, COSV55590304; called by muse, mutect2, varscan2
- PTPN3 | c.2385C>T p.T795= | Splice Region (SNP) | VAF 18/67 reads (27%) | catalogued as rs759615816, COSV52709163; called by muse, mutect2, varscan2
- PTPRN2 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 79/402 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV67062075; called by muse, mutect2, varscan2
- PXDN | c.4129T>G p.S1377A | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53247623; called by muse, mutect2, varscan2
- PYGO2 | c.405del p.F136Sfs*25 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | catalogued as COSV100868881; called by mutect2, pindel, varscan2
- RAB11B | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as COSV60086502; called by muse, mutect2, varscan2
- RAB11FIP2 | c.4A>C p.M2L | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV62926312; called by muse, mutect2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RANBP2 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs757637271, COSV99311684; called by muse, mutect2, varscan2
- RAPGEF6 | c.1918del p.S640Vfs*59 | Frame Shift Del (DEL) | VAF 32/155 reads (21%) | catalogued as rs752725730; called by mutect2, varscan2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as rs760908242; called by mutect2, varscan2
- RASAL1 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1203486700, COSV55660349; called by muse, mutect2
- RASSF7 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.069); catalogued as COSV100272507; called by muse, mutect2, varscan2
- RBKS | c.901A>C p.S301R | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56088434; called by muse, mutect2, varscan2
- RBM12 | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58295643; called by muse, mutect2
- RBM4 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs748197738, COSV59520444; called by muse, mutect2, varscan2
- RBM7 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV64956026; called by muse, mutect2, varscan2
- RBMS3 | c.1148C>T p.T383M (on ENST00000383767 / NM_001003793.3; = p.T367M on NM_014483.3) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs199569162, COSV56156004; called by muse, mutect2, varscan2
- RCOR1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753513724, COSV51773217; called by muse, mutect2, varscan2
- RD3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs1393013845, COSV65362418, COSV65362986; called by muse, mutect2, varscan2
- RGS18 | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100817747, COSV66510304; called by muse, mutect2, varscan2
- RGS9 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.243); catalogued as COSV52229933; called by muse, mutect2, varscan2
- RIBC1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV51448996; called by muse, mutect2, varscan2
- RIMKLA | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.114); catalogued as COSV68910027; called by muse, mutect2, varscan2
- RIMS1 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99325521; called by mutect2, varscan2
- RLF | c.4865G>A p.R1622H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs150236303; called by muse, mutect2, varscan2
- RNF111 | c.1801A>G p.I601V | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774208427, COSV62090350; called by muse, mutect2, varscan2
- RNF157 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs377719776; called by muse, mutect2, varscan2
- ROBO2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778332221, COSV59906905; called by muse, mutect2, varscan2
- ROCK2 | c.2297G>A p.C766Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV59966577; called by muse, mutect2
- RPAP1 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs199855799, COSV58536973, COSV58542958; called by muse, mutect2, varscan2
- RPAP2 | c.1686A>G p.S562= | Splice Region (SNP) | VAF 8/73 reads (11%) | catalogued as COSV72101695; called by mutect2, varscan2
- RPGRIP1L | c.633-1G>C p.X211_splice | Splice Site (SNP) | VAF 7/92 reads (8%) | catalogued as COSV50919718; called by muse, mutect2
- RPS9 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV57191026; called by muse, mutect2, varscan2
- RPTOR | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | catalogued as COSV60819792; called by muse, mutect2
- RTKN | c.1612del p.L538Sfs*117 (on ENST00000272430 / NM_001015055.2; = p.L525Sfs*117 on NM_033046.2) | Frame Shift Del (DEL) | VAF 74/248 reads (30%) | catalogued as rs1054567891; called by mutect2, pindel, varscan2
- RTN4RL1 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV58678801; called by muse, mutect2, varscan2
- RUNX3 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV58246274; called by muse, mutect2, varscan2
- RXFP4 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.102); catalogued as COSV58148570; called by muse, mutect2, varscan2
- RXRG | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312820672, COSV63233305; called by muse, mutect2, varscan2
- SAMD7 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV59421960; called by muse, mutect2, varscan2
- SAMM50 | c.1008-1G>T p.X336_splice | Splice Site (SNP) | VAF 14/125 reads (11%) | catalogued as COSV63109791, COSV63110853; called by muse, mutect2, varscan2
- SCN10A | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV71862795; called by muse, mutect2
- SDK2 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.735); catalogued as rs775786137, COSV66198394; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEC24C | c.2553G>T p.M851I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV59545417; called by muse, mutect2, varscan2
- SECISBP2L | c.1413del p.K471Nfs*20 (on ENST00000559471 / NM_001193489.2; = p.K426Nfs*20 on NM_014701.4) | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs768725524; called by mutect2, varscan2
- SELENON | c.839C>A p.A280D | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62524129, COSV62526589; called by muse, mutect2, varscan2
- SEMA6D | c.2366A>G p.K789R (on ENST00000316364 / NM_153618.2; = p.K727R on NM_020858.2) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.06); catalogued as COSV60374610, COSV60385107; called by muse, mutect2, varscan2
- SEMG2 | c.963A>C p.K321N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV65648058; called by muse, mutect2
- SEPTIN4 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100050911, COSV57898107; called by muse, mutect2
- SETD2 | c.4775G>A p.R1592Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57439624, COSV57447701; called by muse, mutect2, varscan2
- SFXN3 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs538356053, COSV56520303; called by muse, mutect2, varscan2
- SGSM2 | c.2964C>G p.I988M (on ENST00000426855 / NM_001098509.2; = p.I1033M on NM_014853.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV51514266; called by muse, mutect2, varscan2
- SIGLECL1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs149546733; called by muse, mutect2, varscan2
- SIN3B | c.1876A>G p.N626D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV56137003; called by muse, mutect2, varscan2
- SIPA1L1 | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs1157733987, COSV62168732; called by muse, varscan2
- SKIDA1 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV71611161; called by muse, mutect2, varscan2
- SLC12A7 | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145103734; called by muse, mutect2, varscan2
- SLC12A7 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53763397; called by muse, mutect2, varscan2
- SLC13A2 | c.997A>C p.S333R | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV104406808, COSV58999384; called by muse, mutect2
- SLC13A4 | c.1508C>A p.A503D | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62463031; called by muse, mutect2, varscan2
- SLC16A9 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68100960; called by muse, mutect2, varscan2
- SLC1A4 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs942888353, COSV52236307; called by muse, mutect2, varscan2
- SLC2A4 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV50302786; called by muse, mutect2, varscan2
- SLC30A1 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65361668; called by muse, mutect2, varscan2
- SLC35D3 | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs757562966, COSV59378476; called by muse, mutect2, varscan2
- SLC39A13 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as rs770839268, COSV61522930; called by muse, mutect2, varscan2
- SLC43A3 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV61451540; called by muse, mutect2, varscan2
- SLC4A2 | c.3432G>A p.M1144I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV52542596; called by muse, mutect2, varscan2
- SLC9A8 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760094888, COSV64291897; called by muse, mutect2, varscan2
- SLCO5A1 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1299663322, COSV52669563; called by muse, mutect2, varscan2
- SLIT2 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs747000768, COSV56580441; called by muse, mutect2, varscan2
- SLITRK2 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV59423518; called by muse, mutect2, varscan2
- SLITRK5 | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV61526988; called by muse, mutect2, varscan2
- SMARCE1 | c.429A>G p.I143M | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV52861923; called by muse, mutect2, varscan2
- SMG5 | c.1778A>G p.Q593R | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV62438274; called by muse, mutect2, varscan2
- SMG5 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs772301844, COSV62435948; called by muse, mutect2, varscan2
- SNCA | c.280T>G p.F94V | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV61137469; called by muse, mutect2
- SNRNP200 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs142216052, COSV60495180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOGA3 | c.1535del p.K512Rfs*14 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | catalogued as rs34142169, COSV64106882; called by mutect2, pindel, varscan2
- SOWAHD | c.452T>A p.V151D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV59650033; called by muse, mutect2
- SOX11 | c.74A>C p.E25A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV58988516; called by muse, mutect2, varscan2
- SOX9 | c.66del p.S23Afs*38 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as COSV55428538; called by mutect2, pindel, varscan2
- SPAG17 | c.2428T>C p.Y810H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60469944; called by muse, mutect2, varscan2
- SPANXN2 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 171/666 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV65129700; called by muse, varscan2
- SPEN | c.6169A>G p.T2057A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV65368164; called by muse, mutect2
- SPON1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59969538; called by muse, varscan2
- SPON1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1554927966, COSV59969549; called by muse, varscan2
- SPTA1 | c.2308T>C p.S770P | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV63760868; called by muse, mutect2, varscan2
- SPTAN1 | c.5848A>G p.K1950E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV63990135; called by muse, mutect2, varscan2
- SRCAP | c.4697C>T p.A1566V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52682358; called by muse, mutect2, varscan2
- SRGAP3 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs764755283, COSV64535505; called by muse, mutect2, varscan2
- SSMEM1 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.742); catalogued as COSV52834566; called by muse, mutect2, varscan2
- ST8SIA6 | c.794T>G p.F265C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66472243; called by muse, mutect2, varscan2
- STAB1 | c.3364dup p.R1122Pfs*37 | Frame Shift Ins (INS) | VAF 50/234 reads (21%) | catalogued as rs563085224; called by mutect2, varscan2
- STAT5B | c.433A>G p.N145D | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.269); catalogued as COSV53186396; called by muse, mutect2, varscan2
- STK24 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV64823934; called by muse, mutect2, varscan2
- STRC | c.5189G>A p.R1730Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs767639785, COSV100294508; called by muse, mutect2, varscan2
- STXBP1 | c.*5del | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | catalogued as rs752807764, COSV58854018; called by mutect2, pindel, varscan2
- SUSD1 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.159); catalogued as COSV62585686; called by muse, mutect2, varscan2
- SYCP1 | c.2792del p.K931Rfs*6 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as COSV101050748; called by mutect2, pindel, varscan2
- SZT2 | c.2360C>T p.A787V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1427497091, COSV100986924; called by muse, mutect2
- TAFA4 | c.312G>C p.W104C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55147272; called by muse, mutect2, varscan2
- TANC2 | c.4864G>A p.V1622I | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.796); catalogued as rs745873428, COSV67342522; called by muse, mutect2, varscan2
- TANGO2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140525489; called by muse, mutect2, varscan2
- TARBP2 | c.432del p.M145Wfs*36 (on ENST00000266987 / NM_134323.2; = p.M124Wfs*36 on NM_004178.4) | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | catalogued as rs750181498, COSV57199030; called by mutect2, pindel, varscan2
- TBC1D14 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV68987491; called by muse, mutect2, varscan2
- TBC1D22B | c.530dup p.M178Nfs*22 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs757209781; called by mutect2, varscan2
- TBC1D4 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs372617227; called by muse, mutect2, varscan2
- TCF12 | c.546del p.V183Sfs*62 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | catalogued as rs1352708150; called by mutect2, pindel, varscan2
- TCHH | c.4984C>T p.R1662C | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs528288947, COSV64278045; called by muse, mutect2
- TCN1 | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV57254960; called by muse, mutect2
- TELO2 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs572277163, COSV51975803, COSV51981760; called by muse, mutect2, varscan2
- TENM3 | c.3163T>G p.L1055V | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV69321460; called by muse, mutect2, varscan2
- TET1 | c.5110C>T p.Q1704* | Nonsense Mutation (SNP) | VAF 15/123 reads (12%) | catalogued as COSV65390114; called by muse, mutect2, varscan2
- TEX2 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.254); catalogued as COSV99366935; called by muse, mutect2, varscan2
- TFE3 | c.1060+2T>C p.X354_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV59949597; called by muse, mutect2, varscan2
- TGM5 | c.1105+2T>C p.X369_splice (on ENST00000220420 / NM_201631.4; = p.X287_splice on NM_004245.4) | Splice Site (SNP) | VAF 21/94 reads (22%) | catalogued as rs539780475, COSV55012657; called by muse, mutect2, varscan2
- TIGD7 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 14/292 reads (5%) | catalogued as COSV51917206; called by muse, mutect2
- TLR5 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.04); catalogued as rs187499609, COSV60561128; called by muse, mutect2, varscan2
- TM2D3 | c.728G>T p.G243V (on ENST00000333202 / NM_078474.3; = p.G217V on NM_025141.3) | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100309802, COSV60881998; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | catalogued as rs760930120; called by mutect2, varscan2
- TM9SF4 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as rs774513801, COSV54112189; called by muse, mutect2, varscan2
- TMEM127 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV51499166; called by muse, mutect2, varscan2
- TMEM132D | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756920052, COSV70607867, COSV70623172; called by muse, mutect2, varscan2
- TMEM259 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as rs201250012, COSV52263971; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs781830688; called by mutect2, varscan2
- TMPRSS11D | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs528745462, COSV52226983; called by muse, mutect2, varscan2
- TMPRSS6 | c.1136T>C p.L379P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60984593; called by muse, varscan2
- TMPRSS9 | c.899C>T p.S300L (on ENST00000648592; = p.S266L on NM_182973.2) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs184338854; called by muse, mutect2, varscan2
- TNFRSF11B | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.937); catalogued as COSV52074657; called by muse, mutect2, varscan2
- TNFSF13 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV53434313; called by muse, mutect2, varscan2
- TNFSF15 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65011045; called by muse, mutect2, varscan2
- TNIP3 | c.434del p.N145Ifs*15 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs1467769330; called by mutect2, pindel, varscan2
- TNPO2 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV63510540; called by muse, mutect2, varscan2
- TNS3 | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs544588940, COSV60799905; called by muse, mutect2, varscan2
- TNXB | c.6026G>A p.R2009Q (on ENST00000647633; = p.R1762Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs547889326, COSV64489337, COSV64490281; called by muse, mutect2, varscan2
- TP53I11 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); catalogued as COSV57534336; called by muse, mutect2
- TRAF2 | c.1288-2A>C p.X430_splice | Splice Site (SNP) | VAF 11/68 reads (16%) | catalogued as COSV56042079; called by muse, mutect2, varscan2
- TRAF4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV52049249; called by muse, mutect2, varscan2
- TRIL | c.258A>C p.R86S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.281); catalogued as COSV59868160; called by muse, mutect2, varscan2
- TRIM35 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59523615; called by muse, mutect2, varscan2
- TRIM35 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1201555843, COSV59524344; called by muse, mutect2, varscan2
- TRIM62 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52223995; called by muse, varscan2
- TRIOBP | c.4436del p.G1479Afs*28 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs756145453; called by mutect2, pindel, varscan2
- TRIP12 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52273899; called by muse, mutect2, varscan2
- TRPA1 | c.2651T>C p.F884S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200123734, COSV51575880; called by muse, mutect2, varscan2
- TRPM6 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV62524671; called by muse, mutect2, varscan2
- TSHZ3 | c.832A>G p.M278V | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV53684911; called by muse, mutect2, varscan2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs752121179, COSV54531581; called by mutect2, pindel, varscan2
- TSPOAP1 | c.4892T>C p.V1631A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52119311; called by muse, mutect2, varscan2
- TTC4 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV64885402; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.90554T>C p.I30185T (on ENST00000591111; = p.I22761T on NM_003319.4) | Missense Mutation (SNP) | VAF 72/360 reads (20%) | PolyPhen probably damaging (0.943); catalogued as COSV60393125; called by muse, mutect2, varscan2
- TTN | c.88052G>T p.G29351V (on ENST00000591111; = p.G21927V on NM_003319.4) | Missense Mutation (SNP) | VAF 40/207 reads (19%) | PolyPhen possibly damaging (0.799); catalogued as COSV60393157; called by muse, mutect2, varscan2
- TTN | c.32551G>A p.E10851K (on ENST00000591111; = p.E9924K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | PolyPhen probably damaging (0.981); catalogued as COSV60393254; called by muse, mutect2, varscan2
- TTYH2 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53913982; called by muse, mutect2, varscan2
- TUFM | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs181219098; called by muse, mutect2, varscan2
- TUT7 | c.2463G>T p.E821D | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52899423; called by muse, mutect2, varscan2
- UACA | c.3461A>G p.Q1154R | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV59860801; called by muse, mutect2
- UBAP1 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52662307; called by muse, mutect2, varscan2
- UBL7 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777060082, COSV63706178; called by muse, mutect2, varscan2
- UHRF1 | c.343G>A p.A115T (on ENST00000612630 / NM_001290050.1; = p.A128T on NM_013282.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs781513693, COSV53576539; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.684); catalogued as COSV51961224; called by muse, mutect2, varscan2
- UMODL1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs756749467, COSV68578469; called by muse, mutect2, varscan2
- UNC5C | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.202); catalogued as rs919830330, COSV71662662; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs767420916; called by mutect2, varscan2
- UPK3A | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV53415635; called by muse, mutect2, varscan2
- USP31 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs148943431; called by muse, mutect2, varscan2
- USP50 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73214368; called by muse, mutect2
- USP51 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.09); catalogued as rs1283000349, COSV72352034; called by muse, mutect2, varscan2
- USP6NL | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1190896155, COSV53209292; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VPS13A | c.8364A>C p.E2788D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62440502; called by muse, mutect2, varscan2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | catalogued as rs757692785; called by mutect2, pindel, varscan2
- VWA8 | c.4910C>T p.A1637V | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65001319; called by muse, mutect2, varscan2
- WDHD1 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV62215981; called by muse, mutect2, varscan2
- WDR25 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100091781, COSV58936490, COSV58940543; called by muse, mutect2, varscan2
- WDR49 | c.651+1G>A p.X217_splice (on ENST00000308378 / NM_001366158.1; = p.X558_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 19/191 reads (10%) | catalogued as COSV57719175; called by muse, mutect2
- WDR90 | c.3038del p.P1013Qfs*98 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs752097396; called by mutect2, pindel, varscan2
- WDR91 | c.1810T>C p.Y604H | Missense Mutation (SNP) | VAF 24/357 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs750122756, COSV60371210, COSV60372269; called by muse, mutect2
- WNK2 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355562656, COSV52963582; called by muse, mutect2, varscan2
- WNK3 | c.3153G>A p.M1051I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV63616227; called by muse, mutect2, varscan2
- XAF1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as rs372380890; called by mutect2, varscan2
- XYLT2 | c.2584G>A p.G862R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368411795; called by muse, mutect2
- YARS2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61402661; called by muse, mutect2, varscan2
- ZBTB4 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs752288006, COSV60981453; called by muse, mutect2
- ZBTB43 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV65095303; called by muse, mutect2, varscan2
- ZC3H18 | c.1166G>T p.R389M | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56328554; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs751577786; called by mutect2, varscan2
- ZCCHC7 | c.579C>A p.N193K | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59721396; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 28/63 reads (44%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFHX3 | c.2486T>C p.M829T | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.972); catalogued as rs1356851583, COSV51706863; called by muse, mutect2, varscan2
- ZFHX3 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 13/187 reads (7%) | catalogued as COSV51730159; called by muse, mutect2
- ZFP64 | c.1655dup p.Q553Sfs*61 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | catalogued as rs760917371; called by mutect2, varscan2
- ZFYVE9 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55101420, COSV99820081; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF138 | c.562del p.I188Ffs*56 (on ENST00000307355 / NM_001367572.1; = p.I162Ffs*56 on NM_006524.4) | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs750123890; called by mutect2, pindel, varscan2
- ZNF251 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs778385554, COSV52959599; called by muse, mutect2, varscan2
- ZNF253 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs1332202825, COSV63039193; called by muse, mutect2, varscan2
- ZNF287 | c.2108C>A p.P703H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV67689236; called by mutect2, varscan2
- ZNF292 | c.4190G>A p.R1397Q | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60547911; called by muse, mutect2, varscan2
- ZNF292 | c.5411A>G p.N1804S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1038588411, COSV60547926; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF354A | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754398741, COSV59985281; called by muse, mutect2, varscan2
- ZNF407 | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370298369; called by muse, mutect2, varscan2
- ZNF416 | c.1774A>G p.N592D | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1385549969, COSV52186014; called by muse, mutect2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF442 | c.935A>G p.E312G | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs377272395; called by muse, mutect2, varscan2
- ZNF468 | c.696del p.K232Nfs*4 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as COSV54697628; called by mutect2, pindel, varscan2
- ZNF473 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs764328881, COSV54522079, COSV99569260; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 28/196 reads (14%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF619 | c.1586A>T p.N529I | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV59031609; called by muse, mutect2, varscan2
- ZNF624 | c.1494del p.K498Nfs*74 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | catalogued as rs34948063, COSV60939671; called by mutect2, varscan2
- ZNF628 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV52702784; called by muse, mutect2, varscan2
- ZNF638 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52498309; called by muse, mutect2, varscan2
- ZNF638 | c.3912del p.G1305Vfs*22 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs1196097264; called by mutect2, varscan2
- ZNF667 | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.146); catalogued as COSV52640153; called by muse, mutect2, varscan2
- ZNF74 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV100677553, COSV62624803; called by muse, mutect2, varscan2
- ZNF786 | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs765249306, COSV60277829; called by muse, mutect2, varscan2
- ZNF787 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54420658; called by muse, mutect2
- ZP2 | c.191T>C p.F64S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV54817409; called by muse, mutect2
- ZSCAN5A | c.1398A>C p.K466N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54232513; called by muse, mutect2, varscan2
- ZSWIM5 | c.2986A>G p.T996A | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.059); catalogued as COSV55802197; called by muse, mutect2, varscan2
- ABCE1 | c.1069del p.M357Wfs*6 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- ABL2 | c.2508dup p.S837Ifs*55 (on ENST00000502732 / NM_007314.4; = p.S822Ifs*55 on NM_005158.5) | Frame Shift Ins (INS) | VAF 14/106 reads (13%) | called by mutect2, varscan2
- ACSL5 | c.642dup p.F215Lfs*2 (on ENST00000354273; = p.F271Lfs*2 on NM_016234.3) | Frame Shift Ins (INS) | VAF 26/180 reads (14%) | called by mutect2, pindel, varscan2
- ACTB | c.577_579del p.L193del | In Frame Del (DEL) | VAF 44/133 reads (33%) | called by mutect2, pindel, varscan2
- ADAM19 | c.1820del p.G607Afs*20 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- AFF3 | c.2747del p.K916Sfs*72 | Frame Shift Del (DEL) | VAF 10/124 reads (8%) | called by mutect2, pindel
- AKAP3 | c.1914del p.R639Gfs*15 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- AKAP9 | c.11307del p.Q3770Sfs*7 (on ENST00000359028; = p.Q3746Sfs*7 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/234 reads (12%) | called by mutect2, pindel, varscan2
- ALX4 | c.1016del p.P339Lfs*12 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- ANK2 | c.11609del p.K3870Rfs*27 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- ARHGAP26 | c.1499dup p.N500Kfs*17 | Frame Shift Ins (INS) | VAF 14/135 reads (10%) | called by mutect2, pindel, varscan2
- ASAH2 | c.383del p.Q128Rfs*33 | Frame Shift Del (DEL) | VAF 24/137 reads (18%) | called by mutect2, pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | called by pindel, varscan2
- BAZ1A | c.219del p.A74Qfs*12 | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | called by mutect2, varscan2
- BTAF1 | c.3756del p.K1252Nfs*23 | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- CALHM5 | c.738del p.F246Lfs*75 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- CDK13 | c.2733del p.K911Nfs*13 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- CEP83 | c.1397del p.N466Mfs*6 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- CSAG1 | c.46dup p.E16Gfs*11 | Frame Shift Ins (INS) | VAF 40/257 reads (16%) | called by mutect2, pindel, varscan2
- CUBN | c.2496del p.P833Lfs*67 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 15/147 reads (10%) | called by mutect2, pindel, varscan2
- DST | c.18027del p.T6010Lfs*38 (on ENST00000361203 / NM_001374722.1; = p.T3707Lfs*38 on NM_015548.5) | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- DST | c.10379del p.L3460* | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- DYNC1LI1 | c.1457del p.K486Sfs*8 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- EDEM3 | c.1243_1245+19del p.X415_splice | Splice Site (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel
- ELF1 | c.332del p.P111Lfs*10 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | called by mutect2, pindel, varscan2
- EPHB1 | c.1259del p.P420Hfs*28 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- FAM133B | c.193del p.M65* | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- FAT4 | c.13599dup p.K4534Efs*21 | Frame Shift Ins (INS) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- FLOT1 | c.522del p.D175Mfs*30 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | called by mutect2, pindel, varscan2
- GPR87 | c.871del p.I291Sfs*22 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- GPR89B | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- HEPACAM | c.100del p.V34* | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- HUWE1 | c.12610_12612del p.K4204del | In Frame Del (DEL) | VAF 10/81 reads (12%) | called by pindel, varscan2
- IL11RA | c.427dup p.R143Pfs*15 | Frame Shift Ins (INS) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- IL1R2 | c.696del p.E233Kfs*6 | Frame Shift Del (DEL) | VAF 45/278 reads (16%) | called by mutect2, varscan2
- INTS2 | c.3300del p.F1100Lfs*26 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- INTS3 | c.1066dup p.V356Gfs*6 | Frame Shift Ins (INS) | VAF 26/114 reads (23%) | called by mutect2, pindel, varscan2
- KCNK4 | c.338del p.T113Kfs*46 | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- KRT28 | c.1155del p.E386Kfs*8 | Frame Shift Del (DEL) | VAF 44/197 reads (22%) | called by mutect2, pindel, varscan2
- KRT28 | c.155del p.G52Afs*37 | Frame Shift Del (DEL) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- LAMA4 | c.4932dup p.M1645Hfs*18 (on ENST00000230538 / NM_001105206.3; = p.M1638Hfs*18 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- LAMB1 | c.4260_4263del p.G1421Rfs*31 | Frame Shift Del (DEL) | VAF 17/180 reads (9%) | called by mutect2, pindel
- MORC1 | c.388del p.S130Lfs*14 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- MOSPD2 | c.1186+1del | Frame Shift Del (DEL) | VAF 15/140 reads (11%) | called by mutect2, varscan2
- MYO15A | c.2922del p.T975Pfs*11 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- MYO1H | c.1613del p.N538Tfs*9 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- MYRF | c.278del p.P93Rfs*7 (on ENST00000278836 / NM_001127392.3; = p.P84Rfs*7 on NM_013279.4) | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- NAV2 | c.6916del p.V2306Cfs*7 (on ENST00000396087 / NM_001244963.2; = p.V2247Cfs*7 on NM_145117.5) | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel, varscan2
- NEIL3 | c.1755del p.K585Nfs*15 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- NLRP13 | c.1917del p.H640Tfs*39 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- NSUN7 | c.128del p.P43Rfs*25 | Frame Shift Del (DEL) | VAF 20/131 reads (15%) | called by mutect2, pindel, varscan2
- NUAK1 | c.637del p.C213Vfs*75 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- ODF2 | c.1859_1860del p.Y620* (on ENST00000434106 / NM_153433.2; = p.Y596* on NM_002540.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.2682del p.K894Nfs*71 (on ENST00000319481 / NM_080597.4; = p.K381Nfs*71 on NM_018030.4) | Frame Shift Del (DEL) | VAF 26/171 reads (15%) | called by mutect2, varscan2
- PDE8A | c.806del p.K269Rfs*8 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by pindel, varscan2
- PDZD8 | c.3346dup p.I1116Nfs*7 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | called by mutect2, varscan2
- PHKG2 | c.913del p.R305Afs*19 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- PI4K2B | c.1435del p.S479Pfs*40 | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | called by mutect2, pindel, varscan2
- PKN3 | c.1392del p.C465Afs*43 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | called by mutect2, pindel, varscan2
- PLAGL2 | c.30del p.W11Gfs*15 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- POLG2 | c.989del p.N330Mfs*9 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | called by mutect2, pindel, varscan2
- PRCC | c.1138del p.Q380Rfs*47 | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | called by mutect2, varscan2
- PRKAR2B | c.1180dup p.R394Kfs*7 | Frame Shift Ins (INS) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- PTCH1 | c.3921del p.R1308Efs*64 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel, varscan2
- RNF121 | c.501_503del p.L167del | In Frame Del (DEL) | VAF 12/73 reads (16%) | called by pindel, varscan2
- ROCK1 | c.3452del p.L1151Cfs*20 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- SALL4 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCN7A | c.1122del p.F374Lfs*4 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- SFRP4 | c.751del p.H251Ifs*15 | Frame Shift Del (DEL) | VAF 16/148 reads (11%) | called by mutect2, pindel, varscan2
- SHPRH | c.1758del p.G587Efs*23 | Frame Shift Del (DEL) | VAF 27/134 reads (20%) | called by mutect2, pindel, varscan2
- SLC22A6 | c.558dup p.I187Hfs*84 | Frame Shift Ins (INS) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- SLC38A10 | c.2974del p.D992Tfs*50 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- SMC6 | c.1895del p.N632Ifs*29 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- SORCS1 | c.2062dup p.E688Gfs*12 | Frame Shift Ins (INS) | VAF 19/136 reads (14%) | called by mutect2, pindel, varscan2
- SP140 | c.2337del p.F779Lfs*17 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, varscan2
- SP140L | c.1476del p.F492Lfs*17 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, varscan2
- SPANXB1 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2
258 further variants in this file (16 protein-altering or splice-affecting, 223 silent, 19 other) are not listed here.
